Somatic mutation profile of tumor specimen TCGA-DJ-A2Q1-01A (aliquot TCGA-DJ-A2Q1-01A-22D-A19J-08) from TCGA case TCGA-DJ-A2Q1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 44.8 years (16,371 days).
Specimen TCGA-DJ-A2Q1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f577257-4e03-4431-82d2-e64bcb035c9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q1-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q1-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14dfa432-5ec5-4d07-bedd-fdd70695f479

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C15orf39 | c.2630C>T p.T877M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767756211, COSV62295578; called by muse, mutect2
- CD209 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV52649167; called by muse, varscan2
- DYNC1I1 | c.224-1G>A p.X75_splice | Splice Site (SNP) | VAF 40/122 reads (33%) | catalogued as COSV61454949; called by muse, mutect2, varscan2
- TRIP12 | c.3045C>A p.Y1015* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV52258444, COSV52262447; called by muse, mutect2, varscan2
- WNK4 | c.3543G>A p.M1181I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- WNK4 | c.3544C>G p.L1182V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ATR | c.1609T>C p.L537= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV63383281; called by muse, mutect2, varscan2
